TCGA case TCGA-09-1673 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: UCSF. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4e6f88de-7624-4719-8234-4c9e5b2e2988

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 50 years; Vital status: Alive.

Diagnoses (1)
1. Serous cystadenocarcinoma, NOS: ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 50.9 years (18,599 days); Year of diagnosis: 2008; Method of diagnosis: Surgical Resection; FIGO stage: Stage IV; Tumor grade: G3; Prior treatment: No; Days to last follow up: 92 days.
   Pathology details: Lymphatic invasion present: Yes; Residual tumor measurement: >20 mm; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 25 days; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Treatment intent type: Adjuvant; Days to treatment start: 25 days; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 92 days; Disease response: With Tumor.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-09-1673-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 3; Intermediate dimension: 1; Shortest dimension: 0.6.
  Slide TCGA-09-1673-01A-01-BS1: Section location: Bottom; Percent tumor cells: 87; Percent tumor nuclei: 99; Percent normal cells: 0; Percent necrosis: 8; Percent stromal cells: 5.
  Slide TCGA-09-1673-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 99; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 5.
- Sample TCGA-09-1673-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Lymphovascular invasion indicator: Yes.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Pharmaceutical therapy drug name: Taxol or Taxotere.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 92 days; disease-specific survival: no event (censored), 92 days; progression-free interval: no event (censored), 92 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-09-1673-01A-01D-0559-01): tumor purity 0.87, ploidy 4.07, whole-genome doublings 1.
